Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7059, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7059-01A (Primary Tumor).

[page 1 of 2]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

A year old man with 4.7 cm right lower pole renal mass

Specimens Submitted:

1. SP: Kidney, right renal tumor, partial nephrectomy (fs)

DIAGNOSIS:

1. SP: Kidney, right renal tumor, partial nephrectomy (fs):

Tumor Type:

Renal cell carcinoma - Papillary type

Fuhrman Nuclear Grade:

N/A

Tumor Size:

Greatest diameter is 4.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arterionephrosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[page 2 of 2]
Gross Description

1. The specimen is received fresh labeled "right renal tumor (stitch marks the deep surgical margin)". It consists of a 7 x 6 x 5 cm wedge shaped portion of kidney with a suture marking the deep margin. The perinephric fat is inked green. The surgical margin is inked black and the specimen is serially sectioned to reveal an encapsulated golden yellow tumor measuring 4.5 x 3.5 x 3.5 cm. The tumor does not appear to be involving the perinephric adipose tissue and the adjacent renal parenchyma. The clearance from the resection margin is 0.4 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. A portion of the tumor is submitted for TPS and representative sections are submitted for examination.

Summary of sections: FSC - frozen section control, T - tumor, SM - surgical margin, PF - perinephric fat

Summary of Sections:

Part 1: SP: Kidney, right renal tumor, partial nephrectomy (fs)

Block	Sect. Site	PCs
1	FSCA	1
1	FSCB	1
1	PF	1
1	SM	1
6	T	8

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Right renal tumor (B): Renal cortical neoplasm; margin at suture (B) is free of tumor
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file ecefba1e-c7b3-4290-bd6a-d0347ead578f (TCGA-BQ-7059.AE429195-07E4-47AD-94F4-9535B560F24D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).